Gene-level copy-number profile of tumor specimen C3L-09552-04 from CPTAC case C3L-09552, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 46.3 years (16,900 days).
Specimen C3L-09552-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 06fd8dd9-7a71-4b94-b29c-9cac14827845.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09552-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,795 have no estimate.
https://portal.gdc.cancer.gov/files/3ac9ef94-5c88-43e9-a1ad-83a52074c61d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 432; copy number 1: 6,880; copy number 2: 44,684; copy number 3: 3,622; copy number 4: 1,825; copy number 5: 707; copy number 6: 355; copy number 7: 84; copy number 8: 51; copy number 9: 24; copy number 10: 32; copy number 11: 22; copy number 12: 3; copy number 13: 23; copy number 14: 16; copy number 15: 2; copy number 16: 4; copy number 18: 7; copy number 19: 3; copy number 20: 5; copy number 24: 2; copy number 26: 27; copy number 27: 1; copy number 28: 14; copy number 58: 1; copy number 93: 1; copy number 106: 1.

Homozygous deletions (total copy number 0; autosomes only): 432 genes in 112 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,551,735–5,668,295, 9 genes: Z98747.1, LINC01646, AJAP1, Z98886.1, LINC02782, Z98259.3, Z98259.1, AL365255.1, Z97988.1.
- chr1:17,717,625–18,388,514, 7 genes: LINC02810, ACTL8, LINC01654, IGSF21, AL365209.1, IGSF21-AS1, AL591896.1.
- chr1:18,630,846–18,859,682, 2 genes (within-gene range 0–2): PAX7, TAS1R2.
- chr1:29,904,865–30,226,615, 4 genes: AL645944.1, LINC01648, AL137076.1, AL021921.1.
- chr1:33,838,523–34,219,131, 5 genes: HSPD1P14, HMGB4, CSMD2-AS1, RNA5SP42, C1orf94.
- chr1:36,630,335–37,034,515, 3 genes: FTLP18, AC117945.1, GRIK3.
- chr1:53,328,233–53,440,020, 5 genes: LINC01771, AC119428.2, AC119428.1, LINC02812, SLC25A3P1.
- chr1:158,694,539–158,743,415, 5 genes: OR6K1P, OR6K2, OR6K3, OR6K4P, OR6K5P.
- chr2:120,464,335–120,992,653, 7 genes: LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1.
- chr2:217,760,547–218,033,982, 4 genes (within-gene range 0–1): RPL7L1P9, TNS1, MIR6809, TNS1-AS1.
- chr2:238,554,541–238,740,849, 3 genes (within-gene range 0–2): LINC01937, AC113618.2, AC113618.1.
- chr3:115,802,363–117,997,592, 18 genes (within-gene range 0–1): LSAMP, RN7SL815P, LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8, RNU6-1200P, AC092691.1, AC092691.2, LINC02024, AC092691.3.
- chr3:126,103,562–126,210,169, 4 genes (within-gene range 0–2): ALDH1L1, ALDH1L1-AS1, RNU1-30P, ALDH1L1-AS2.
- chr3:127,202,372–127,390,670, 5 genes: Y_RNA, AC112482.1, RNU6-1047P, PRR20G, LINC02016.
- chr4:67,909,395–68,039,647, 4 genes (within-gene range 0–2): TMPRSS11A, TMPRSS11GP, RNU6-95P, GCOM2.
- chr5:135,559,577–135,889,770, 7 genes: AC034206.1, CXCL14, SLC25A48, SLC25A48-AS1, AC011431.1, MIR5692C1, AC114296.1.
- chr5:179,377,505–179,385,992, 3 genes: AC109479.3, AC109479.1, AC109479.2.
- chr6:40,271,566–40,387,590, 4 genes: AL139275.2, TDRG1, LINC00951, AL139275.1.
- chr6:49,823,712–49,969,625, 5 genes: AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113.
- chr8:141,514,638–142,209,003, 6 genes: AC138647.1, AC104417.1, AC104417.2, AC103758.1, MIR4472-1, LINC00051.
- chr9:65,287,914–65,894,790, 11 genes: CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3.
- chr9:67,059,560–67,329,404, 5 genes: CNTNAP3P2, RN7SL422P, AL162233.1, RBM17P2, BX005195.1.
- chr9:117,759,455–118,083,382, 3 genes: AL160272.1, AL354754.1, TPT1P9.
- chr9:134,641,803–135,121,180, 16 genes: COL5A1, COL5A1-AS1, AL645768.1, MIR3689C, MIR3689A, MIR3689D1, MIR3689B, MIR3689D2, MIR3689E, MIR3689F, AL603650.1, FCN2, FCN1, AL353611.1, AL353611.2, OLFM1.
- chr10:71,212,570–71,302,864, 2 genes: UNC5B, UNC5B-AS1.
- chr10:123,574,227–123,940,267, 5 genes (within-gene range 0–1): AL357127.1, GPR26, CPXM2, AC009987.1, AC068058.1.
- chr12:16,548,372–16,610,594, 2 genes (within-gene range 0–2): LMO3, AC007552.2.
- chr12:52,263,948–52,652,211, 26 genes: AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C, KRT6A, KRT5, KRT71, KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2.
- chr12:97,530,656–97,532,958, 2 genes (within-gene range 0–2): AC018659.4, AC018659.3.
- chr12:130,121,925–130,165,740, 5 genes: AC026336.4, AC026336.3, FZD10-AS1, AC026336.5, FZD10.
- chr12:131,292,068–131,371,721, 7 genes: RPS6P20, AC092850.1, LINC02415, RNA5SP376, LINC02370, AC140118.2, AC140118.1.
- chr13:78,275,720–78,286,288, 2 genes (within-gene range 0–3): AL138957.1, SRGNP1.
- chr14:100,675,930–101,066,801, 111 genes (within-gene range 0–1) (broad region; genes not listed).
- chr14:101,217,372–101,408,258, 4 genes: AL355836.1, AL359682.1, AL355096.1, LINC00524.
- chr15:74,202,705–74,336,472, 4 genes (within-gene range 0–2): CCDC33, AC023300.3, AC023300.1, AC023300.2.
- chr17:73,749,270–73,836,019, 3 genes (within-gene range 0–1): LINC00469, LINC02092, AC125421.2.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:28,883,430–28,970,874, 4 genes (within-gene range 0–1): LINC00906, AC008991.1, AC011524.1, AC011524.2.
- chr19:43,035,869–43,284,318, 9 genes (within-gene range 0–2): CEACAMP8, PSG2, CEACAMP9, AC005392.1, PSG5, PSG4, CEACAMP10, PSG9, CEACAMP11.
- chr22:48,448,890–49,214,247, 6 genes: Z82249.1, TAFA5, Z84468.1, MIR4535, LINC01310, RPL35P8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,385 genes in 241 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:31,865,060–32,618,899, 16 genes, copy number 5–8 (within-gene range 3–8): MEMO1, DPY30, AL121655.1, SPAST, AL121658.1, SLC30A6, DDX50P1, RNU6-647P, NLRC4, YIPF4, AL133245.1, BIRC6, BIRC6-AS1, AL133243.2, AL133243.3, MIR558.
- chr2:89,252,211–89,990,221, 24 genes, copy number 6–14: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA, IGKV2D-40, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV3D-25.
- chr2:90,021,567–90,154,574, 10 genes, copy number 6–10: IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13.
- chr2:90,172,802–91,723,605, 18 genes, copy number 7–20: IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2.
- chr2:200,870,907–201,103,136, 14 genes, copy number 5–6: PPIL3, RNU6-312P, NIF3L1, RNU6-762P, ORC2, AC005037.1, FAM126B, HNRNPA1P35, RPL23AP30, NDUFB3, RNU6-1206P, Metazoa_SRP, AC007272.1, RPL17P10.
- chr3:171,941,607–172,725,038, 15 genes, copy number 5 (within-gene range 5–6): AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2.
- chr4:39,498,755–39,977,956, 17 genes, copy number 5–6: UGDH, UGDH-AS1, AC021148.2, SMIM14, AC108471.3, RNU7-11P, AC108471.2, UBE2K, Y_RNA, AC108471.1, RN7SL558P, ZBTB12BP, PDS5A, ELOCP33, RNA5SP159, AC098591.3, PABPC1P1.
- chr4:48,805,212–49,246,915, 14 genes, copy number 5–8: OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr5:37,085,056–37,753,435, 12 genes, copy number 5–6 (within-gene range 2–6): RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5.
- chr5:69,093,949–69,595,221, 23 genes, copy number 5–6: SLC30A5, AC010273.2, AC010273.1, SNORA50D, CCNB1, AC022107.1, CENPH, MRPS36, CDK7, CCDC125, CFL1P5, CHCHD2P2, NDUFB9P1, AK6, TAF9, RAD17, MARVELD2, RPS27P14, AC145146.1, RN7SL616P, OCLN, RNU6-724P, GTF2H2C.
- chr5:80,111,651–80,542,563, 16 genes, copy number 5: SERINC5, AC010260.1, KRT18P45, AC026410.1, AC026410.4, AC026410.2, SPZ1, RBMX2P5, AC026410.3, HNRNPA1P12, RNU6-211P, ZFYVE16, AC008771.1, FAM151B, RPS27AP9, RPL7P24.
- chr6:73,394,828–73,653,992, 10 genes, copy number 6–7 (within-gene range 4–7): DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15.
- chr6:110,700,562–111,047,521, 12 genes, copy number 5–6: AL512430.2, AL603914.1, RNU6-957P, SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1, AL357515.1, GTF3C6, RPF2, GSTM2P1.
- chr9:4,676,600–4,885,917, 10 genes, copy number 5: CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1, AL353151.1, RCL1, KLF4P1, MIR101-2, AL158147.1.
- chr9:60,914,407–64,082,534, 81 genes, copy number 6 (broad region; genes not listed).
- chr9:66,047,084–66,992,583, 20 genes, copy number 7–18 (within-gene range 3–18): AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P, CDRT15P12, RBPJP2, RAB28P4, ATP5F1AP10, SDR42E1P4, FKBP4P8, ZNF658, BX664608.1, AL353770.4, AL353770.2, FAM74A3, AL353770.3, AL353770.1, SPATA31A3.
- chr9:67,512,034–68,644,442, 24 genes, copy number 5–13 (within-gene range 2–13): BX664730.1, Y_RNA, FAM27E3, AL627230.3, FAM27B, AL627230.1, RN7SL787P, SNORA70, AL627230.2, ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252, TMEM252-DT, LINC01506.
- chr10:21,481,716–22,003,769, 11 genes, copy number 5 (within-gene range 3–6): Y_RNA, MIR1915HG, MIR1915, SKIDA1, MLLT10, RNU6-306P, HNRNPRP1, RNU6-1141P, DNAJC1, RN7SKP219, AL359697.1.
- chr10:68,106,117–68,694,487, 18 genes, copy number 5: MYPN, RN7SKP202, ATOH7, LINC02640, KRT19P4, PBLD, HNRNPH3, RUFY2, DNA2, RPL26P29, RNA5SP319, SLC25A16, RPL26P27, Y_RNA, TMEM14DP, TET1, COX20P1, RPS3AP37.
- chr11:33,004,250–33,357,023, 12 genes, copy number 5–6 (within-gene range 2–6): Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294, CSTF3, CSTF3-DT, Y_RNA, RPL29P23, Y_RNA, AL136126.1, HIPK3.
- chr12:101,745,499–102,012,130, 12 genes, copy number 5 (within-gene range 2–6): GNPTAB, RNU6-101P, AC063950.1, RNA5SP368, RNU6-172P, RNA5SP369, RNU6-1183P, HSPE1P4, DRAM1, AC084398.2, AC084398.1, AC079907.2.
- chr13:19,633,659–20,567,045, 21 genes, copy number 5–7: MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2, ZMYM2, KRR1P1, AL138688.2, LINC01072, GJA3, PPIAP28, LINC00556, GJB2, AL138688.1, GJB6, CRYL1, MIR4499, AL590096.1.
- chr13:45,120,510–45,436,660, 15 genes, copy number 5–8: GTF2F2, RN7SKP4, AL138693.1, KCTD4, AL138963.2, TPT1, SNORA31B, SNORA31, AL138963.3, TPT1-AS1, AL138963.1, RCN1P2, SLC25A30, SLC25A30-AS1, PPIAP25.
- chr13:49,444,374–50,125,720, 25 genes, copy number 5–7 (within-gene range 3–7): SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr14:30,893,799–31,420,550, 13 genes, copy number 6–8 (within-gene range 2–8): STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2.
- chr14:34,485,979–34,875,647, 15 genes, copy number 5 (within-gene range 3–5): RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A.
- chr14:49,552,633–49,913,760, 30 genes, copy number 5–6: RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP.
- chr14:58,244,843–58,427,531, 11 genes, copy number 5 (within-gene range 2–5): PSMA3, AL132989.1, PSMA3-AS1, HMGB1P14, LINC00216, RNU6-341P, ARID4A, AL139021.2, TOMM20L, AL139021.1, TIMM9.
- chr14:63,543,569–64,338,112, 20 genes, copy number 5–6 (within-gene range 3–6): AL136038.3, AL136038.1, GCATP1, WDR89, AL136038.2, HSPE1P2, RNU6-597P, Y_RNA, RNU6-1162P, AL136038.4, U3, SGPP1, EIF2S2P1, RNU7-116P, SYNE2, AL161670.1, RPS28P1, Y_RNA, ESR2, MIR548H1.
- chr14:106,821,174–106,879,812, 10 genes, copy number 9: IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr15:58,760,466–59,097,419, 11 genes, copy number 5 (within-gene range 0–6): SNORD3P1, AC090515.2, MINDY2, AC090515.5, AC090515.4, ZNF444P1, RNF111, AC090515.1, SLTM, AC025918.1, AC025918.2.
- chr16:34,015,260–35,086,119, 18 genes, copy number 5–14: AC133561.4, AC133561.3, AC136932.1, DUX4L45, PCMTD1P2, DUX4L46, DUX4L47, LINC00273, RNA5-8SP2, BCLAF1P2, AC135776.4, LINC02184, AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11, NAMPTP3.
- chr16:46,469,341–46,931,289, 18 genes, copy number 10: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2.
- chr17:59,422,088–60,018,975, 19 genes, copy number 5 (within-gene range 3–5): LINC01476, RNU4-13P, DHX40, AC091271.1, CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1.
- chr18:3,025,069–3,478,978, 17 genes, copy number 5: AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:31,829,197–32,131,561, 16 genes, copy number 5–7 (within-gene range 3–7): TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2.
- chr19:20,122,569–20,809,995, 34 genes, copy number 5 (within-gene range 2–7): AC011447.3, AC011447.1, AC011447.2, BNIP3P15, ZNF486, BNIP3P16, AC011447.4, AC011447.6, AC011447.7, BNIP3P17, AC078899.3, AC078899.1, BNIP3P18, AC078899.4, BNIP3P19, AC078899.5, ZNF826P, BNIP3P20, AC078899.2, MIR1270, BNIP3P22, AC008554.1, BNIP3P23, ZNF737, AC010636.2, VN1R78P, AC010636.1, ZNF626, AC010329.5, AC010329.2, AC010329.1, VN1R79P, ZNF66, BNIP3P24.
- chr21:7,744,962–9,129,752, 42 genes, copy number 11–106: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:10,122,273–13,120,807, 18 genes, copy number 19–28 (within-gene range 19–51): CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:15,326,037–16,141,872, 24 genes, copy number 5–11: ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, MED15P7, POTEH-AS1, RNU6-816P, PSLNR, GRAMD4P2, DUXAP8, AP000526.1, BMS1P22, AP000525.1, DUXAP8, NBEAP3, TOMM40P2, AP000522.1, AC145543.1, U6.

Autosomal genes at a single copy (total copy number 1): 4,024. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
